Surgical pathology report (de-identified scan), TCGA case TCGA-23-1116, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1116-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

A. OMENTUM AND MESENTERY, PARTIAL OMENTECTOMY AND EXCISION OF MESENTERY:

- Mullerian-derived adenocarcinoma with serous and anaplastic features, extensive (see comment)

B. FALLOPIAN TUBE AND OVARY, RIGHT, SALPINGO-OOPHORECTOMY:

- Mullerian-derived adenocarcinoma, high-grade, with serous and anaplastic features, involving:
- Serosal aspect of fallopian tube
- Ligamentous of adnexal soft tissues, extensively in paraovarian region
- Regional lymphovascular spaces
- Ovary with atrophic changes, cystic epithelial inclusions, hyperplastic hilus cell nests, myxoid and edematous stromal changes in hilar region, and serosal adhesion
- Fallopian tube also shows chronic inflammation and serosal adhesions
- Paratubal cystic Walthard rests

C. FALLOPIAN TUBE AND OVARY, LEFT, SALPINGO-OOPHORECTOMY:

- Mullerian-derived adenocarcinoma, high grade, with serous and anaplastic features involving:
- Extensively ligamentous adnexal soft tissues adjacent to both ovary and fallopian tube
- Serosal surface of ovary and ovarian parenchyma (see comment)
- Fimbriated end of fallopian tube, serosal surface of fallopian tube and muscular wall of fallopian tube
- Regional lymphovascular spaces
- Ovary also shows atrophic changes, a benign serous cystadenofibroma, cystic epithelial inclusions, and serosal adhesions
- Paraovarian mesothelial cyst
- Fallopian tube also shows serosal adhesions and chronic and minimal acute inflammation
- Paratubal Walthard rests
- Microscopic leiomyoma within adnexal ligament

D. UTERUS, TOTAL ABDOMINAL HYSTERECTOMY:

- Metastatic adenocarcinoma involving serosal surface of uterus, subserosa, parametrial tissues, and regional lymphovascular spaces

[page 2 of 5]
PATIENT: [REDACTED]

- No evidence of carcinoma at surgical margin of cervix
- Multiple large endometrial polyps
- Endometrium with relatively weak proliferative features and some cystically dilated glands
- Adenomyosis
- Multiple uterine leiomyomas, two of those sampled show extensive though patchy areas of hyalinization and a larger of these two is also calcified
- Cervix with chronic and mild acute inflammation, reactive squamous changes, squamous metaplasia, cystic endocervical tunnel clusters, and nabothian cysts

E. SOFT TISSUE, ANTERIOR ABDOMINAL WALL:

- Metastatic adenocarcinoma

COMMENT: In both adnexa, the bulk of the tumor involves the ligamentous soft tissues and there is a huge volume of tumor in the omentum; therefore, a peritoneal primary carcinoma is considered in the differential diagnosis. However, since there is also invasive tumor measuring more than 1 cm in the left ovary, by convention, this would be considered a primary ovarian neoplasm. Pathologic tumor stage is assigned as follows: pT3c, NX, MX. Preliminary pathologic findings were conveyed to [REDACTED]. Immunohistochemical stains, performed subsequently, confirm the müllerian derivation of the neoplasm. Results of the immunostains are listed below.

HISTORY: Prior breast carcinoma

MICROSCOPIC:

See diagnosis.

SPECIAL STUDIES: None

IMMUNOSTAINS:

All immunostains were performed on formalin-fixed paraffin-embedded tissue from block C2.

Cytokeratin 7: Most tumor cells exhibit positive staining.

Cytokeratin 20: Difficult to interpret due to high background staining and staining of borders of nests of tumor cells; no specific cytoplasmic staining of tumor cells appreciated.

WT-1: Most tumor cells exhibit positive nuclear staining.

CA 125: Most tumor cells exhibit positive staining.

CA 19.9: Few neoplastic cells stain positively.

CEA: Few neoplastic cells stain positively.

Mammaglobin: No specific staining of tumor cells.

GCDFP-15: No specific staining of tumor cells.

Estrogen receptor: Greater than 75% of the tumor cells stain positively; staining intensity ranges from +1 to

+3.

Progesterone receptor: No specific staining of neoplastic cells.

GROSS:

A. OMENTUM, MESENTERY TUMOR

Labeled with the patient's name, labeled "omentum, mesentery tumor", received fresh in the Operating Room for frozen section, and subsequently fixed in formalin, is a 23.5 x 21.0 x 3.0 cm partial omentectomy and mesenterectomy specimen. The specimen consists of lobulated yellow adipose tissue that is infiltrated by firm, tan-white tumor. In aggregate, tumor measures about 14.0 x 6.0 x 3.0 cm in greatest overall dimensions.

[page 3 of 5]
PATIENT: [REDACTED]

PATH #: [REDACTED]

Representative sections are submitted.

Slide key:

- A1. Remnant of frozen section #1 - 1
- A2. Unfrozen tissue with tumor - 1
- A3. Unfrozen tissue with tumor - 1

B. RIGHT TUBE PLUS OVARY

Labeled with the patient's name, labeled "right tube and ovary", and received fresh in the Operating Room and subsequently fixed in formalin, is a salpingo-oophorectomy specimen. The ovary is 3.6 x 1.3 x 0.9 cm. The fallopian tube with fimbria is 11.5 cm long and ranges from 0.4 to 0.7 cm in diameter.

There is a 2.0 x 1.0 x 0.7 cm firm tan tumor that involves mostly the paraovarian ligamentous tissue. The ovary itself appears tumor free. The tumor also involves the mesosalpinx and there is a 0.2 cm diameter firm tan tumor nodules on the serosal aspect of the fallopian tube.

The ovary is atrophic and shows several small cysts, the largest of which is about 0.3 cm in diameter. Serosal adhesions are also noted on the fallopian tube and ovary..

Representative sections are submitted.

Slide key:

- B1. Fallopian tube - 3
- B2. Tumor - 2
- B3. Ovary - 1

Additional representative sections (submitted on [REDACTED] fallopian tube and ovary now entirely embedded):

- B4. Ovary and paraovarian tumor - 2
- B5. Ovary - 1
- B6. Fallopian tube - Multiple
- B7. Fallopian tube - Multiple
- B8. Fallopian tube - Multiple
- B9. Fallopian tube - Multiple

C. LEFT TUBE PLUS OVARY

Labeled with the patient's name, labeled "left tube plus ovary", and received fresh in the Operating Room and subsequently fixed in formalin, is a 33 gram salpingo-oophorectomy specimen. The ovary is 4.4 x 1.6 x 1.6 cm. The fimbriated fallopian tube is 4.0 cm long and ranges from 0.6 to 1.0 cm in diameter.

There is a 4.0 x 3.8 x 3.0 cm firm white-tan tumor that extensive involves the paraovarian and paratubal ligamentous soft tissues and also involves the ovarian serosal surface and invades the ovary. Plaque-like and nodular aggregates of similar appearing tumor also involve the serosa of the fallopian tube and fimbria.

The ovary also shows a 1.6 x 0.9 x 0.6 cm cystic and solid intraparenchymal mass that is composed partly of firm tan-white tissue and partly of tiny to small cystic spaces, the latter of which measure up to about 0.5 cm in diameter. Attached to the ovary, there is a 1.2 x 1.0 x 0.9 cm fluid-filled thin-walled cyst that is lined by smooth tan tissue. Except for the deposits of tumor on the outer aspect, the fallopian tube is grossly unremarkable.

Representative sections are submitted.

Slide key:

- C1. Fallopian tube - 3
- C2. Ovary - 1

[page 4 of 5]
PATIENT: [REDACTED]

- C3. Ovary - 1
- C4. Ovary - 2
- C5-C9. Tumor (mostly paraovarian) - 1 each

Additional representative sections (submitted on [REDACTED] fallopian tube now entirely embedded):

C10. Fallopian tube - multiple

D. UTERUS, CERVIX

Labeled with the patient's name, labeled "uterus, cervix", and received in formalin is a 170 gram intact total hysterectomy specimen. The uterus is 10.3 x 7.6 x 5.0 cm in greatest overall dimensions. The cervical portion of the uterus is about 3.2 cm long and up to 3.1 cm in diameter. The external cervical os is 1.2 cm in diameter. The endometrial cavity is about 4.2 cm long and up to 3.7 cm in width. The flat endometrial mucosa has a maximum thickness of about 0.2 cm. The muscular uterine wall is up to about 1.7 cm in thickness.

The serosal surface of the uterus is studded by multiple firm tan tumor nodules which range in size from 0.1 to 2.7 cm in maximum dimension. No invasive tumor is evident on gross inspection of the uterus. The cervix appears grossly free of tumor.

The uterus also shows three circumscribed leiomyomas that range from about 1.0 to 5.6 cm in maximum dimension. Some are subserosal and others are intramural. The leiomyomas are each composed of firm solid tan-white whorled tissue without grossly evident areas of hemorrhage or necrosis. The endometrium also shows three semisoft tan polyps, two of which are located in the posterior uterine corpus and one of which is in the anterior corpus. The polyps range from 2.2 to 3.2 cm in maximum dimension. The cervix is remarkable only for a few mucus-filled cysts the largest of which is 0.3 cm in diameter.

Representative sections are submitted.

Slide key:

- D1. Anterior cervix - 1
- D2. Posterior cervix - 1
- D3. Anterior uterine corpus - 1
- D4. Posterior uterine corpus - 1
- D5, D6. One polyp from anterior uterus, bisected - 1 each
- D7. One polyp from posterior uterus - 1
- D8. Second polyp from posterior uterus - 1
- D9-D12. Tumor implants on serosa of uterus - 1 each
- D13. Two leiomyomas - 2
- D14. Largest leiomyoma - 2

E. ANTERIOR ABDOMINAL WALL

Labeled with the patient's name, labeled "anterior abdominal wall", and received in formalin is a 4.5 x 3.6 x 0.5 cm portion of yellow-tan fibroadipose tissue that shows a 0.7 x 0.5 x 0.3 cm plaque-like aggregate of firm tan tumor. Representative sections are submitted.

Slide key:

- E1. Tumor - 2

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN):

A. OMENTUM (FROZEN SECTION #1):

- Metastatic poorly differentiated carcinoma

[page 5 of 5]
PATIENT: [REDACTED]

PATH #: [REDACTED]

OPERATIVE CALL

B. RIGHT OVARY PLUS TUBE (TISSUE PROCUREMENT):

- Portion of benign ovary submitted [REDACTED]

C. LEFT OVARY PLUS TUBE (TISSUE PROCUREMENT):

OPERATIVE CALL

OPERATIVE CONSULT (GROSS):

D. UTERUS (ORIENTATION PLUS GROSS PLUS TISSUE PROCUREMENT):

- Uterus with serosal tumor implants, leiomyomas, and endometrial polyps

Source: NCI Genomic Data Commons file 77c9ac17-cc1f-47eb-870a-c1f64ef22ac6 (TCGA-23-1116.D39C8F94-C4F0-4166-864B-912D7535F2B6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).